Somatic mutation profile of tumor specimen TCGA-34-2609-01A (aliquot TCGA-34-2609-01A-01W-0877-08) from TCGA case TCGA-34-2609, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 81.8 years (29,871 days).
Specimen TCGA-34-2609-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3558d247-4478-4a0b-ae02-02362c954f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2609-11A (Solid Tissue Normal), aliquot TCGA-34-2609-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2843a3ce-7037-48d6-93ba-7f4b0625acc3

The open-access MAF lists 262 somatic variants for this specimen: 199 protein-altering or splice-affecting, 54 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 54, Nonsense Mutation 11, Frame Shift Del 6, Splice Site 6, Frame Shift Ins 4, Intron 3, RNA 3, 3'UTR 1, In Frame Del 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.193A>T p.R65* | Nonsense Mutation (SNP) | VAF 439/856 reads (51%) | catalogued as rs1555526721, COSV52689560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99656687; called by muse, mutect2, varscan2
- ABHD2 | c.411C>A p.H137Q | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as COSV100756240; called by muse, mutect2, varscan2
- ACE | c.639A>C p.E213D | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV99326754; called by muse, mutect2
- ACE | c.3625C>T p.R1209C | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs1353694784, COSV99326758; called by muse, mutect2, varscan2
- ADAM15 | c.763G>C p.V255L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99664901; called by muse, mutect2, varscan2
- ADAM23 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as COSV100007243; called by muse, mutect2, varscan2
- ADGRB3 | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 14/392 reads (4%) | catalogued as COSV65413081; called by muse, mutect2
- ADGRL3 | c.272C>G p.A91G (on ENST00000506720 / NM_001322402.2; = p.A23G on NM_015236.6) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101546983; called by muse, varscan2
- AKR1C3 | c.462T>G p.C154W | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201818208; called by mutect2, varscan2
- AMTN | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 67/131 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100219672, COSV59489048; called by muse, mutect2, varscan2
- APCS | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV54819122, COSV99661251; called by muse, mutect2
- APOB | c.13564G>T p.D4522Y | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs767091894, COSV99264854; called by muse, mutect2, varscan2
- ARRDC4 | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV99164343; called by muse, mutect2, varscan2
- ATG4C | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100508017; called by muse, mutect2, varscan2
- ATP13A4 | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99794324; called by muse, mutect2
- BDKRB2 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100021038; called by muse, mutect2
- BMPER | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99779353; called by muse, mutect2, varscan2
- BTBD8 | c.1010A>T p.D337V | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.366); catalogued as COSV100730203; called by muse, mutect2, varscan2
- C12orf42 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs1222458305, COSV100172030; called by muse, mutect2, varscan2
- CA6 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 72/348 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101077466; called by muse, mutect2, varscan2
- CAB39 | c.385A>G p.M129V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99299782; called by muse, mutect2, varscan2
- CALD1 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 42/123 reads (34%) | catalogued as COSV100724139, COSV100724648; called by muse, mutect2, varscan2
- CD163L1 | c.1024A>T p.R342* | Nonsense Mutation (SNP) | VAF 83/218 reads (38%) | catalogued as rs143956577; called by muse, mutect2, varscan2
- CDH10 | c.2209G>T p.A737S | Missense Mutation (SNP) | VAF 69/393 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52573112, COSV52584409; called by muse, mutect2, varscan2
- CDH10 | c.1988G>T p.G663V | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52580048; called by muse, mutect2, varscan2
- CDH10 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 180/963 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050899; called by muse, mutect2, varscan2
- CDH18 | c.2030G>T p.R677M | Missense Mutation (SNP) | VAF 107/441 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56900908, COSV56928101; called by muse, mutect2, varscan2
- CFAP57 | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 141/576 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100763999; called by muse, mutect2, varscan2
- CLHC1 | c.1434G>T p.Q478H | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101284868; called by muse, mutect2, varscan2
- CNTNAP4 | c.3114C>G p.S1038R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV100270519, COSV56679445; called by muse, varscan2
- CPM | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.151); catalogued as COSV100615012; called by muse, mutect2, varscan2
- CSMD3 | c.9956T>A p.F3319Y (on ENST00000297405 / NM_001363185.1; = p.F3150Y on NM_052900.3) | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99830664; called by muse, mutect2, varscan2
- CST9 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as rs770383370, COSV100980472, COSV100980502; called by muse, mutect2, varscan2
- CYP24A1 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs571886397, COSV53773343; called by muse, mutect2, varscan2
- DGKI | c.903G>T p.M301I | Missense Mutation (SNP) | VAF 56/397 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV99933430; called by muse, mutect2, varscan2
- DHCR7 | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV100831852; called by mutect2, varscan2
- DNAJC8 | c.665G>T p.S222I | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99746176; called by muse, mutect2, varscan2
- DPPA4 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.285); catalogued as COSV100169357; called by muse, mutect2, varscan2
- DROSHA | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 227/724 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100757413, COSV100757561; called by muse, mutect2, varscan2
- EBF2 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV101282137; called by muse, mutect2, varscan2
- EPS8L3 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 528/774 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV100719693; called by muse, varscan2
- ESYT1 | c.3299A>G p.D1100G | Missense Mutation (SNP) | VAF 81/425 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99919874; called by muse, mutect2, varscan2
- FAM217A | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV99212711; called by muse, mutect2, varscan2
- FANCL | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99287415; called by muse, mutect2, varscan2
- FAT3 | c.2978G>T p.R993L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs539020470, COSV53072565; called by muse, mutect2
- FRMPD4 | c.3148C>A p.Q1050K | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.029); catalogued as COSV101042595; called by muse, mutect2, varscan2
- FUS | c.1484G>T p.R495L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as CD1110975, COSV99568499; called by muse, mutect2, varscan2
- GALNT6 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100695380; called by muse, varscan2
- GAP43 | c.56A>T p.K19M | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100525458; called by muse, mutect2, varscan2
- GLP2R | c.1489C>A p.L497I | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52329540, COSV99301861; called by muse, mutect2, varscan2
- GLRA3 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as rs765420954, COSV99927339; called by muse, mutect2, varscan2
- GPC6 | c.1289G>T p.R430I | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100988371; called by muse, mutect2, varscan2
- GRHPR | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as rs750954346, COSV100546874; ClinVar: uncertain significance; called by muse, mutect2
- GRID1 | c.2922dup p.L975Afs*86 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs780877661; called by pindel, varscan2
- GRIK2 | c.2306C>G p.P769R | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100024821, COSV59738132; called by muse, mutect2, varscan2
- GSTA3 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV99274493; called by muse, mutect2
- HCN1 | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1219412264, COSV100299639; called by muse, varscan2
- HCN3 | c.1623G>T p.M541I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100712866; called by muse, mutect2, varscan2
- HERC1 | c.5119C>G p.Q1707E | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.9); catalogued as COSV101496493; called by muse, mutect2
- HLA-DRB5 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100894442; called by muse, varscan2
- HYAL2 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99222693; called by muse, mutect2, varscan2
- IL17F | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as COSV100277163, COSV60234235; called by muse, mutect2, varscan2
- INTS13 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.757); catalogued as COSV99677274; called by muse, mutect2
- ITIH2 | c.1281C>A p.G427= | Splice Region (SNP) | VAF 13/137 reads (9%) | catalogued as rs769442335, COSV100623249, COSV100623445; called by muse, mutect2
- ITPR1 | c.1703G>T p.R568M (on ENST00000354582; = p.R553M on NM_002222.7) | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100230622; called by muse, mutect2, varscan2
- ITPR1 | c.1704G>T p.R568S (on ENST00000354582; = p.R553S on NM_002222.7) | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100230623; called by muse, mutect2, varscan2
- KIF5A | c.1413C>A p.S471R | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV54058175; called by muse, mutect2, varscan2
- KIR2DL1 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 144/1477 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV99382951, COSV99383651; called by muse, mutect2
- KIR2DL4 | c.1097C>A p.T366N (on ENST00000396284; = p.T292N on NM_001080770.2) | Missense Mutation (SNP) | VAF 250/1035 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV100428483; called by muse, mutect2, varscan2
- LAMA2 | c.4670G>T p.C1557F | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101370334; called by muse, mutect2, varscan2
- LCE2B | c.274T>G p.C92G | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.479); catalogued as COSV100909295; called by muse, mutect2, varscan2
- LHCGR | c.643A>C p.N215H | Missense Mutation (SNP) | VAF 182/863 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV99683467; called by muse, mutect2, varscan2
- LNPEP | c.2362G>T p.A788S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99183510, COSV99183540; called by muse, mutect2, varscan2
- LRRC66 | c.1274T>C p.F425S | Missense Mutation (SNP) | VAF 65/432 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100602911; called by muse, varscan2
- LRRC66 | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 118/432 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV100602912; called by muse, varscan2
- MAML1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as COSV99483034; called by muse, mutect2, varscan2
- MAP9 | c.482-1G>C p.X161_splice | Splice Site (SNP) | VAF 26/142 reads (18%) | catalogued as COSV100250837; called by muse, mutect2, varscan2
- MC3R | c.809C>G p.T270S | Missense Mutation (SNP) | VAF 62/500 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV99710523; called by muse, mutect2, varscan2
- MCM3 | c.2417A>G p.N806S (on ENST00000229854 / NM_001366374.2; = p.N796S on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/630 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs573829677; called by muse, mutect2, varscan2
- MYBPC1 | c.943C>G p.Q315E (on ENST00000550270 / NM_206820.2; = p.Q340E on NM_002465.4) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100637737, COSV100637879; called by muse, mutect2, varscan2
- MYBPC2 | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100731740; called by muse, mutect2, varscan2
- MYF5 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 33/320 reads (10%) | catalogued as rs370171499, COSV57356172; called by muse, mutect2, varscan2
- MYH1 | c.898C>G p.L300V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV99875486; called by muse, mutect2, varscan2
- MYH8 | c.5166+1G>C p.X1722_splice | Splice Site (SNP) | VAF 81/280 reads (29%) | catalogued as COSV101238357; called by muse, mutect2, varscan2
- MYO1F | c.2270G>C p.G757A | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV100596548; called by muse, mutect2, varscan2
- NAV3 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.637); catalogued as COSV99889263; called by muse, mutect2, varscan2
- NFYB | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV99527150; called by muse, mutect2, varscan2
- NID2 | c.133dup p.D45Gfs*54 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs1566780400; called by mutect2, pindel
- NRAP | c.2449G>T p.A817S (on ENST00000359988 / NM_001322945.2; = p.A782S on NM_006175.4) | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV100748376; called by muse, mutect2, varscan2
- OFD1 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100406840; called by muse, mutect2, varscan2
- OR10H5 | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 78/696 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as rs766738019, COSV100454683, COSV58279306; called by muse, mutect2
- OR4B1 | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100535554; called by muse, mutect2, varscan2
- OR4P4 | c.746T>C p.F249S | Missense Mutation (SNP) | VAF 22/369 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100111663; called by muse, mutect2
- OR52A5 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100263376, COSV56614457; called by muse, mutect2, varscan2
- OR52H1 | c.101G>T p.C34F (on ENST00000322653; = p.C40F on NM_001005289.1) | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs779468835, COSV59505558; called by muse, mutect2, varscan2
- OR5L1 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 158/702 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); catalogued as rs61998198, COSV100450006, COSV61733363; called by muse, mutect2, varscan2
- OR6C65 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV101110180; called by muse, mutect2, varscan2
- OSBPL6 | c.2751G>A p.W917* | Nonsense Mutation (SNP) | VAF 26/150 reads (17%) | catalogued as COSV99507099; called by muse, mutect2, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, mutect2, varscan2
- PARP1 | c.1223T>G p.V408G | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs79529505; called by mutect2, varscan2
- PCDH11X | c.743T>A p.V248D | Missense Mutation (SNP) | VAF 124/339 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV100010680; called by muse, mutect2, varscan2
- PCDH15 | c.3990G>T p.L1330F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100218547; called by mutect2, varscan2
- PCDH15 | c.3506C>A p.T1169N | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.898); catalogued as COSV100218550; called by muse, mutect2, varscan2
- PCDHA7 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV100971371; called by muse, mutect2
- PDE11A | c.140T>A p.I47K | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV100628636; called by muse, mutect2, varscan2
- POLH | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100947728; called by muse, mutect2, varscan2
- PPP4R1 | c.1940A>G p.Y647C (on ENST00000400556 / NM_001042388.3; = p.Y630C on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 199/553 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs910655495, COSV99553360; called by muse, mutect2, varscan2
- PREPL | c.845G>C p.G282A | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.069); catalogued as COSV99576073; called by muse, mutect2, varscan2
- PRKG1 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs761501836, COSV100907226; called by muse, mutect2
- PRLR | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51493174, COSV99184297; called by muse, varscan2
- PRPF8 | c.4298A>C p.D1433A | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100517349; called by muse, mutect2
- PSG3 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 668/3586 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV100548844; called by muse, varscan2
- PSG6 | c.357C>A p.Y119* | Nonsense Mutation (SNP) | VAF 245/1934 reads (13%) | catalogued as COSV99413844; called by muse, varscan2
- PTPRR | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV99316971; called by muse, mutect2, varscan2
- PTPRS | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.109); catalogued as COSV53619532, COSV99509985; called by muse, mutect2, varscan2
- PTPRT | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 156/326 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100626438; called by muse, mutect2, varscan2
- PZP | c.1285C>A p.H429N | Missense Mutation (SNP) | VAF 122/365 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99737252; called by muse, mutect2, varscan2
- R3HDM1 | c.2654C>G p.P885R | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99926019; called by muse, mutect2, varscan2
- RAB11B | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV100033013; called by muse, mutect2, varscan2
- RAD18 | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs757759853, COSV99368269; called by muse, mutect2, varscan2
- RIMS2 | c.1932G>C p.W644C (on ENST00000666250 / NM_001348490.2; = p.W452C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51649822, COSV99166068; called by muse, mutect2, varscan2
- RP1 | c.3719C>A p.S1240Y | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV99606995; called by muse, mutect2
- RPL17-C18orf32 | c.254A>T p.K85I | Missense Mutation (SNP) | VAF 8/267 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV59087092; called by muse, mutect2
- RPL6 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV99176121; called by muse, mutect2, varscan2
- RYR1 | c.7793C>A p.A2598E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100615354, COSV62090807; called by muse, mutect2, varscan2
- SALL1 | c.2490A>C p.E830D | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV99173113; called by muse, mutect2, varscan2
- SATL1 | c.169A>G p.S57G (on ENST00000395409; = p.S244G on NM_001012980.2) | Missense Mutation (SNP) | VAF 105/182 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100260755; called by muse, mutect2, varscan2
- SCFD2 | c.588G>C p.K196N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV101189330; called by muse, mutect2, varscan2
- SERINC4 | c.538+1G>T p.X180_splice | Splice Site (SNP) | VAF 22/408 reads (5%) | catalogued as COSV99988343; called by muse, mutect2
- SERINC4 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 23/409 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV99988346; called by muse, mutect2
- SLC12A6 | c.2024G>A p.R675Q (on ENST00000354181 / NM_001365088.1; = p.R624Q on NM_005135.2) | Missense Mutation (SNP) | VAF 33/576 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99271565; called by muse, mutect2
- SLC22A2 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs766277243; called by muse, mutect2, varscan2
- SLC24A5 | c.997T>A p.Y333N | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV99981411; called by muse, mutect2, varscan2
- SLC26A5 | c.292+2T>G p.X98_splice | Splice Site (SNP) | VAF 85/244 reads (35%) | catalogued as COSV100099007; called by muse, mutect2, varscan2
- SMG6 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 119/259 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as rs1567762456, COSV99558009; called by muse, mutect2, varscan2
- SPAG6 | c.590A>T p.H197L | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100510155; called by muse, mutect2, varscan2
- SPRR3 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV54881265, COSV99768492; called by muse, varscan2
- STXBP5L | c.3206T>A p.F1069Y | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); catalogued as COSV99873243; called by muse, mutect2, varscan2
- TAAR2 | c.355T>A p.Y119N (on ENST00000367931 / NM_001033080.1; = p.Y74N on NM_014626.3) | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99255595; called by muse, mutect2, varscan2
- TARS2 | c.779C>A p.S260* | Nonsense Mutation (SNP) | VAF 28/317 reads (9%) | catalogued as COSV100945920; called by muse, mutect2
- TBC1D10B | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1049763939; called by muse, mutect2
- TLL1 | c.1794G>T p.Q598H | Missense Mutation (SNP) | VAF 120/543 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV50313366, COSV50327864; called by muse, mutect2, varscan2
- TMCC1 | c.1618C>G p.Q540E (on ENST00000393238 / NM_001349268.2; = p.Q216E on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/299 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61439493; called by muse, mutect2, varscan2
- TMEM200A | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV51649569, COSV99759006; called by muse, mutect2, varscan2
- TNFRSF13B | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs867307644, COSV99891411; called by muse, mutect2, varscan2
- TNR | c.1334G>T p.W445L | Missense Mutation (SNP) | VAF 112/734 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54881069; called by muse, mutect2, varscan2
- TRIM23 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99139927; called by muse, mutect2
- TRIM48 | c.571T>A p.L191I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV70162016; called by muse, mutect2, varscan2
- TRMT6 | c.1028T>C p.I343T | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99177546; called by muse, mutect2
- TTC21B | c.3613G>A p.D1205N | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99692133; called by muse, mutect2, varscan2
- TTN | c.56932G>T p.V18978F (on ENST00000591111; = p.V11554F on NM_003319.4) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | PolyPhen benign (0.238); catalogued as rs1377163743, COSV100604401; called by muse, mutect2, varscan2
- UBR4 | c.11014G>T p.G3672* | Nonsense Mutation (SNP) | VAF 15/141 reads (11%) | catalogued as COSV100920666; called by muse, mutect2, varscan2
- UGGT2 | c.2201-1G>T p.X734_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100948581; called by muse, varscan2
- UGT3A1 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99954594; called by muse, mutect2, varscan2
- UTRN | c.3109G>C p.D1037H | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs200581848, COSV100839783, COSV100840754; called by muse, mutect2
- VN1R4 | c.794T>C p.L265S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as rs772394999, COSV100237479; called by mutect2, varscan2
- VNN2 | c.214-2A>T p.X72_splice | Splice Site (SNP) | VAF 35/135 reads (26%) | catalogued as COSV58472772; called by muse, mutect2, varscan2
- VPS13B | c.11371G>T p.A3791S | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100661581; called by muse, mutect2
- VRTN | c.979_980insT p.G327Vfs*27 | Frame Shift Ins (INS) | VAF 14/113 reads (12%) | catalogued as COSV99832194; called by mutect2, pindel
- WARS1 | c.67G>C p.V23L | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV100690118, COSV59925963; called by muse, mutect2, varscan2
- XDH | c.2502G>T p.M834I | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs765724627, COSV101052149; called by muse, mutect2, varscan2
- XKR3 | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 110/354 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100509201; called by muse, mutect2, varscan2
- ZBED6CL | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1382641688, COSV100550439; called by muse, mutect2, varscan2
- ZFHX4 | c.5849C>T p.T1950I | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1223506129, COSV99260970; called by muse, varscan2
- ZFP36 | c.304G>T p.A102S (on ENST00000594442; = p.A96S on NM_003407.5) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as COSV99953753; called by muse, mutect2, varscan2
- ZG16B | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66525832, COSV66525942; called by muse, mutect2
- ZNF302 | c.1196A>G p.K399R (on ENST00000627982; = p.K320R on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1323709654, COSV101416462; called by muse, mutect2
- ZNF423 | c.193G>T p.D65Y (on ENST00000563137 / NM_001379286.1; = p.D57Y on NM_015069.4) | Missense Mutation (SNP) | VAF 201/543 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.123); catalogued as COSV99280928; called by muse, mutect2, varscan2
- ZNF649 | c.683A>T p.H228L | Missense Mutation (SNP) | VAF 67/486 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100030949; called by muse, mutect2, varscan2
- ZNF780A | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100575041; called by muse, mutect2, varscan2
- ZSCAN2 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.65); catalogued as COSV100491460; called by mutect2, varscan2
- AP2B1 | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.017); called by muse, mutect2
- ARHGAP24 | c.205A>G p.K69E | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CFHR4 | c.1622del p.T541Kfs*30 (on ENST00000367416 / NM_001201551.2; = p.T295Kfs*30 on NM_006684.5) | Frame Shift Del (DEL) | VAF 51/172 reads (30%) | called by mutect2, pindel, varscan2
- CSMD1 | c.3413A>T p.E1138V (on ENST00000520002; = p.E1137V on NM_033225.6) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DCBLD1 | c.1357+1del | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, varscan2
- FGFR2 | c.801_803dup p.T268dup | In Frame Ins (INS) | VAF 47/150 reads (31%) | called by mutect2, pindel, varscan2
- IL27RA | c.394dup p.R132Pfs*5 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- KCNIP4 | c.408_409del p.H136Qfs*30 | Frame Shift Del (DEL) | VAF 20/193 reads (10%) | called by pindel, varscan2
- KDM6A | c.2580del p.E861Nfs*6 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, varscan2
- LRRK2 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MED13 | c.5275C>G p.L1759V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYOM3 | c.3472del p.A1158Qfs*70 | Frame Shift Del (DEL) | VAF 64/308 reads (21%) | called by mutect2, pindel, varscan2
- NRXN3 | c.665G>T p.C222F | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR2V2 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2
- OSTC | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PCDHA3 | c.1856_1857del p.R619Hfs*37 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by pindel, varscan2
- PCLO | c.12731G>T p.G4244V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTGER4 | c.148_150del p.K50del | In Frame Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- RASSF2 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.122); called by muse, mutect2
- SPIDR | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 139/621 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- SRCIN1 | c.2729G>T p.G910V (on ENST00000621492; = p.G876V on NM_025248.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNJ1 | c.2262G>T p.M754I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- TBC1D15 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- TOP2B | c.3073G>T p.D1025Y (on ENST00000264331 / NM_001330700.2; = p.D1020Y on NM_001068.3) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV10 | c.209T>A p.I70N | Missense Mutation (SNP) | VAF 43/568 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2
- ZFYVE27 | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- ZNF639 | c.1205C>G p.P402R | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAN | c.5277C>A p.S1759= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100717683; called by muse, mutect2
- AMPD3 | c.1140G>A p.R380= (on ENST00000396553 / NM_001025389.2; = p.R389= on NM_000480.3) | Silent (SNP) | VAF 58/192 reads (30%) | catalogued as COSV101158134; called by muse, mutect2, varscan2
- ANO7 | c.1152G>T p.L384= (on ENST00000274979; = p.L330= on NM_001370694.2) | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV99237987; called by muse, mutect2, varscan2
- APOB | c.13563T>A p.I4521= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV51949873, COSV99264856; called by muse, mutect2, varscan2
- ARMC4 | c.2895G>T p.V965= | Silent (SNP) | VAF 71/294 reads (24%) | catalogued as COSV100536579; called by muse, mutect2, varscan2
- CBR1 | c.708G>C p.A236= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99289431; called by muse, mutect2, varscan2
- CCDC150 | c.567G>T p.S189= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as COSV55873851, COSV55874197; called by muse, mutect2, varscan2
- CD1B | c.552C>T p.C184= | Silent (SNP) | VAF 84/297 reads (28%) | catalogued as rs1470701293, COSV100939202; called by muse, mutect2, varscan2
- COL8A1 | c.573G>T p.G191= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- CUL3 | c.1113G>T p.A371= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100023961; called by muse, mutect2, varscan2
- CYB5D2 | c.669C>T p.T223= | Silent (SNP) | VAF 21/258 reads (8%) | catalogued as rs534144144, COSV100028914; called by muse, mutect2
- CYP4F8 | c.279C>T p.G93= | Silent (SNP) | VAF 62/229 reads (27%) | catalogued as rs763950295; called by muse, mutect2, varscan2
- DLGAP5 | c.606G>A p.S202= | Silent (SNP) | VAF 172/463 reads (37%) | catalogued as rs377000715; called by muse, mutect2, varscan2
- DNAH3 | c.10065G>T p.L3355= | Silent (SNP) | VAF 276/914 reads (30%) | catalogued as rs755332249, COSV54549037, COSV99766316; called by muse, mutect2, varscan2
- DOCK11 | c.4656C>T p.F1552= | Silent (SNP) | VAF 61/115 reads (53%) | catalogued as rs746053640, COSV99353473; called by muse, mutect2, varscan2
- ELAPOR2 | c.2751G>A p.K917= (on ENST00000450689 / NM_001142749.3; = p.K750= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 74/242 reads (31%) | catalogued as COSV99788566; called by muse, mutect2, varscan2
- EPHB1 | c.2457A>T p.S819= | Silent (SNP) | VAF 106/675 reads (16%) | catalogued as COSV101212964; called by muse, mutect2, varscan2
- F9 | c.1266C>G p.T422= | Silent (SNP) | VAF 100/203 reads (49%) | catalogued as COSV99496477; called by muse, mutect2, varscan2
- FLRT2 | c.1188G>A p.T396= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs200412416, COSV58143947; called by muse, mutect2, varscan2
- GHRHR | c.1098C>A p.S366= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- GRM1 | c.9G>T p.G3= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV99265331; called by muse, mutect2, varscan2
- IL1RAPL2 | c.534G>C p.V178= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV100781097; called by muse, mutect2, varscan2
- IL21R | c.1530C>A p.P510= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV61972612; called by mutect2, varscan2
- INTS8 | c.2427G>T p.V809= | Silent (SNP) | VAF 37/174 reads (21%) | catalogued as COSV100569220; called by muse, mutect2, varscan2
- ITIH6 | c.2301C>A p.I767= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV54492106, COSV99513120; called by muse, mutect2, varscan2
- KLHL28 | c.1422G>T p.V474= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV100753056, COSV61888374; called by muse, mutect2, varscan2
- KMT2C | c.5199G>T p.S1733= | Silent (SNP) | VAF 297/1039 reads (29%) | catalogued as COSV100070217, COSV51309675; called by muse, mutect2, varscan2
- LAP3 | c.948C>A p.I316= | Silent (SNP) | VAF 39/254 reads (15%) | catalogued as COSV99884205; called by muse, mutect2, varscan2
- LRTM2 | c.1005C>T p.Y335= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs750674817, COSV54564397; called by muse, mutect2, varscan2
- MECOM | c.264T>C p.P88= | Silent (SNP) | VAF 62/583 reads (11%) | catalogued as rs781527004, COSV101527902; called by muse, mutect2, varscan2
- MRPL42 | c.276G>A p.L92= | Silent (SNP) | VAF 59/317 reads (19%) | called by muse, mutect2, varscan2
- MTUS2 | c.786G>T p.V262= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV101462155, COSV101462372; called by muse, varscan2
- NDNF | c.1704T>C p.C568= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV65633969; called by muse, mutect2, varscan2
- NR1D2 | c.1200A>G p.E400= | Silent (SNP) | VAF 29/239 reads (12%) | catalogued as COSV100437363; called by muse, mutect2, varscan2
- OR13G1 | c.501G>T p.G167= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as COSV100687158; called by muse, mutect2, varscan2
- OR2M2 | c.735C>A p.L245= | Silent (SNP) | VAF 106/782 reads (14%) | catalogued as COSV100677213; called by muse, mutect2, varscan2
- OR4K5 | c.330G>A p.G110= | Silent (SNP) | VAF 76/1075 reads (7%) | catalogued as rs747328075, COSV100262282; called by muse, mutect2
- OR4L1 | c.117G>T p.V39= | Silent (SNP) | VAF 276/498 reads (55%) | catalogued as COSV100235638; called by muse, mutect2, varscan2
- OTOL1 | c.1029G>T p.S343= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs1464684146, COSV100019691, COSV100020258; called by muse, mutect2
- PCGF1 | c.726C>T p.F242= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs758463215; called by muse, varscan2
- PLCE1 | c.3747C>T p.S1249= | Silent (SNP) | VAF 106/623 reads (17%) | catalogued as rs530724888, COSV53368555; called by muse, mutect2, varscan2
- PRAMEF8 | c.936C>A p.L312= | Silent (SNP) | VAF 22/532 reads (4%) | called by muse, mutect2
- PTCHD1 | c.1005C>A p.V335= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV101037427; called by muse, mutect2, varscan2
- PTPN13 | c.792A>T p.G264= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100364510; called by muse, mutect2, varscan2
- RGL1 | c.33G>T p.S11= (on ENST00000360851 / NM_001297672.2; = p.S46= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100486421, COSV58982544; called by muse, mutect2, varscan2
- SEC14L4 | c.831G>A p.Q277= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99742846; called by muse, mutect2, varscan2
- SEC31A | c.1158G>T p.P386= | Silent (SNP) | VAF 96/320 reads (30%) | catalogued as COSV100021751; called by muse, mutect2, varscan2
- SLC26A3 | c.528G>A p.V176= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV100384977; called by muse, mutect2, varscan2
- SPAG16 | c.1030C>T p.L344= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100531287, COSV59121050; called by muse, mutect2, varscan2
- SPATA21 | c.1089C>T p.P363= | Silent (SNP) | VAF 66/271 reads (24%) | catalogued as rs868255331, COSV100130785; called by muse, mutect2, varscan2
- SPEG | c.7920G>A p.Q2640= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- SRCAP | c.5205A>T p.A1735= | Silent (SNP) | VAF 73/319 reads (23%) | catalogued as COSV99349795; called by muse, mutect2, varscan2
- STXBP5 | c.2292A>G p.L764= (on ENST00000321680 / NM_001127715.2; = p.L728= on NM_139244.4) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV51654342; called by muse, mutect2
- ZNF799 | c.1128T>C p.H376= | Silent (SNP) | VAF 175/838 reads (21%) | catalogued as rs748194148, COSV101345251; called by muse, varscan2
- CD200R1 | c.68-16741C>T | Intron (SNP) | VAF 30/144 reads (21%) | catalogued as COSV99867050; called by muse, mutect2, varscan2
- CPLANE1 | c.*5297T>C | 3'UTR (SNP) | VAF 92/321 reads (29%) | catalogued as COSV99950187, COSV99950287; called by muse, mutect2, varscan2
- DENND10P1 | n.473del | RNA (DEL) | VAF 148/359 reads (41%) | called by mutect2, pindel, varscan2
- FAM183BP | n.1315G>A | RNA (SNP) | VAF 105/889 reads (12%) | called by muse, mutect2, varscan2
- MIR543 | n.14G>A | RNA (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- OR51S1 | c.-2C>A | 5'UTR (SNP) | VAF 31/401 reads (8%) | catalogued as COSV100437416; called by muse, mutect2
- OR52A4P | chr11:5121117 C>T | 3'Flank (SNP) | VAF 33/202 reads (16%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-12843C>G | Intron (SNP) | VAF 85/771 reads (11%) | called by muse, mutect2, varscan2
- UROC1 | c.903-607C>G | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99331193; called by muse, mutect2, varscan2
